Gene-level copy-number profile of tumor specimen TCGA-55-7726-01A from TCGA case TCGA-55-7726, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 72.4 years (26,451 days).
Specimen TCGA-55-7726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.677ac9ea-f03b-4e88-a733-5fa65fd5d0e2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-55-7726-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/466cfd8b-8949-4d47-91d0-23d7868837af

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 2,076; copy number 2: 3,207; copy number 3: 17,497; copy number 4: 17,187; copy number 5: 9,540; copy number 6: 6,376; copy number 7: 1,718; copy number 8: 2,059; copy number 9: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-55-7726-01A-11D-2166-01): tumor purity 0.26, ploidy 4.09, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,090,898–9,442,380, 2 genes: RPS26P3, RN7SL5P.
- chr9:20,658,309–23,438,700, 65 genes (broad region; genes not listed).
- chr9:24,542,952–31,254,777, 57 genes: IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36, RPS26P2, FTLP4, HSPA8P17, AL354854.1, SLC25A6P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,813 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 8 (broad region; genes not listed).
- chr7:70,972–79,453,667, 1,497 genes, copy number 7–8 (within-gene range 6–8) (broad region; genes not listed).
- chr9:97,853,226–98,708,935, 16 genes, copy number 8 (within-gene range 4–8): FOXE1, TRMO, Y_RNA, AL499604.1, HEMGN, ANP32B, AL354726.1, RNU6-918P, NANS, TRIM14, Metazoa_SRP, CORO2A, TBC1D2, MIR6854, AL360081.1, GABBR2.
- chr9:99,396,987–101,793,756, 41 genes, copy number 8 (within-gene range 4–8): AL359710.1, STX17-AS1, AL162394.1, NR4A3, STX17, AL358937.1, ERP44, UPF3AP3, INVS, RN7SL75P, RPS2P35, AL137072.1, NANOGP5, TEX10, MSANTD3, MSANTD3-TMEFF1, TMEFF1, CAVIN4, RN7SKP87, ACTG1P19, AL162395.1, GAPDHP26, PLPPR1, AL161631.1, AL359893.2, ACNATP, BAAT, TRMT112P4, AL359893.1, FYTTD1P1, MRPL50, ZNF189, ALDOB, AL353621.2, TMEM246-AS1, PGAP4, AL353621.1, RNF20, GRIN3A, PPP3R2, MTND3P4.
- chr17:79,598,032–80,253,500, 26 genes, copy number 7: AC233701.1, MIR4739, LINC02078, ENPP7, CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1, LINC01979, LINC01978, TBC1D16, AC100791.3, AC116025.2, AC116025.1, CCDC40, MIR1268B, GAA, EIF4A3, AC087741.3, AC087741.2, CARD14, AC087741.1, SGSH, SLC26A11.
- chr17:80,315,651–80,316,633, 1 gene, copy number 7: AC124319.1.
- chr18:2,537,525–3,478,978, 36 genes, copy number 9: METTL4, AP005136.1, AP005136.3, AP005136.2, NDC80, KATNBL1P3, Y_RNA, RNU6-340P, CBX3P2, SMCHD1, AP001011.1, Y_RNA, EMILIN2, LPIN2, AP000919.3, CHORDC1P4, AP000919.1, AP000919.2, SNRPCP4, AP005431.1, SNORA70, MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC.
- chr18:13,183,402–14,632,806, 52 genes, copy number 7: AP001198.2, AP001198.1, LDLRAD4, AP002505.1, C18orf15, AP002505.3, AP002505.2, AP002439.1, LDLRAD4-AS1, MIR5190, AP005131.5, AP005131.4, AP005131.2, AP005131.1, AP005131.3, MIR4526, AP001010.1, FAM210A, AP001525.1, RN7SL362P, RNMT, MC5R, MC2R, AP001086.1, AC006557.6, AC006557.5, ZNF519, AC006557.4, AC006557.1, AC006557.3, FRG2LP, AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3.
- chr20:87,250–10,058,303, 227 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr20:10,025,917–10,026,168, 1 gene, copy number 7: Metazoa_SRP.
- chr20:11,536,406–64,313,132, 1,206 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,178. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
